MMRF case MMRF_1269 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a34db4a9-6e9d-4f42-9dd8-de810570c4a3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 1,590 days (4.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.5 years (19,163 days); ISS stage: I; Days to last known disease status: 1,590 days (4.4 years); Days to last follow up: 1,590 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 103 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days; Days to treatment end: 1,462 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,475 days (4.0 years); Days to treatment end: 1,538 days (4.2 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,544 days (4.2 years); Days to treatment end: 1,590 days (4.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,590.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16: M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.6 mg/dL; Immunoglobulin G 33.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.7 mmol/L; Albumin 44 g/L; Total Protein 9.5 g/dL; Glucose 5.61 mmol/L.
- Day 64: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 5 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 6.38 mmol/L.
- Day 152 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 14.8 ×10⁹/L; Absolute Neutrophil 12.5 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.6 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 7.81 mmol/L.
- Day 236 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 7.08 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 376: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 0.444 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 432 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.71 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.493 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 551 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 0.761 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 607 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.82 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 663 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 9.38 g/L; Immunoglobulin A 0.792 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 775 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Immunoglobulin G 9.67 g/L; Immunoglobulin A 0.892 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 4.18 mmol/L.
- Day 859 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 0.839 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 950 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.6 mg/dL; Immunoglobulin G 9.4 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.24 mmol/L.
- Day 1,041 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.84 mmol/L.
- Day 1,132 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.4 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.205 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.
- Day 1,222 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.9 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 1,307 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5 mg/dL; Immunoglobulin G 9.16 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 1,398 (ECOG 0): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 115 mg/dL; Immunoglobulin G 33 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 174 ×10⁹/L.
- Day 1,502 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69.5 mg/dL; Immunoglobulin G 22.2 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.13 ×10⁹/L; Platelets 13 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 7.3 g/dL; Glucose 5.56 mmol/L.
- Day 1,566 (ECOG 2): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 178 mg/dL; Immunoglobulin G 41.5 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 0.4 ×10⁹/L; Absolute Neutrophil 0 ×10⁹/L; Platelets 7 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 1.9 mmol/L; Albumin 21 g/L; Total Protein 6.9 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -16: Weight: 109 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1269_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1269_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
